TARGET case TARGET-52-PARKKN — Rhabdoid Tumor (TARGET-RT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Lip.
https://portal.gdc.cancer.gov/cases/26b56e63-cd15-52ee-aaf4-ca89354317d0

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 6 years; Vital status: Alive.

Diagnoses (1)
1. Malignant rhabdoid tumor: ICD-O-3 morphology code: 8963/3; ICD-10 code: C64; Tissue or organ of origin: External upper lip; Classification of tumor: primary; Age at diagnosis: 6.4 years (2,355 days); Year of diagnosis: 2007; Pediatric kidney staging: Tumor biopsied only at diagnosis, no distant metastasis.
   Treatment given: Protocol identifier: AREN03B2.

Follow-up (2 entries)
- Year of follow up: 2007; Timepoint: Last Contact.
- Follow-up contact recording only the day: follow-up.

Biospecimens (1 sample)
- Sample TARGET-52-PARKKN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_RT_ClinicalData_Discovery_and_Validation_Percent_Tumor_Nuclei_and_Necrosis_Supplement_20230322.xlsx (sheet RT Data), for sample TARGET-52-PARKKN-01A-01:
- Histological Subtype: rhabdoid
- Specimen Type: frozen solid tumor
- Adequate Tissue (Y/N): Y
- Pathology: Diagnosis Confirmed: yes
- % Tumor Nuclei: Top: 70
- % Non tumor Nuclei: Top: 30
- % Cellular Tumor: Top: 70
- % Normal: Top: 30
- % Stroma: Top: 0
- % Necrosis: Top: 0
- % Tumor Nuclei: Bottom: 75
- % Non tumor Nuclei: Bottom: 25
- % Cellular Tumor: Bottom: 75
- % Normal: Bottom: 25
- % Stroma: Bottom: 0
- % Necrosis: Bottom: 0
- Pathology Pass/Fail: fail

Additional fields from the TARGET clinical supplement workbook TARGET_RT_ClinicalData_Discovery_and_Validation_Supplement_20230322.xlsx, for sample TARGET-52-PARKKN-01A-01D:
- Cohort: Validation
- Anatomical site of tumour: Soft tissue
- Stage of the primary tumour at the time of diagnosis: 3

Additional fields from the TARGET clinical supplement workbook TARGET_RT_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Stage: IIIB
- ICD-O-3-T: C000
- Histologic Classification of Primary Tumor: RT
